Somatic mutation profile of tumor specimen 0DFXH2 from CCDI case PBBSRF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 3.2 years (1,156 days).
Specimen 0DFXH2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ce3b310-3131-475e-b7cd-8f3e138ca25f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFXF2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/940430ba-cac5-4325-a297-d583b452376f

The open-access MAF lists 54 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 11, Intron 6, 5'UTR 3, Nonsense Mutation 2, 3'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2033del p.P678Rfs*10 | Frame Shift Del (DEL) | VAF 124/458 reads (27%) | catalogued as rs587781807, CX1511110; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AHNAK | c.11495A>T p.D3832V | Missense Mutation (SNP) | VAF 136/2061 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200444226; called by muse, mutect2
- ARHGEF17 | c.5488C>T p.R1830W | Missense Mutation (SNP) | VAF 94/1474 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1456066766; called by muse, mutect2
- CSMD3 | c.5395G>T p.V1799L (on ENST00000297405 / NM_001363185.1; = p.V1695L on NM_052900.3) | Missense Mutation (SNP) | VAF 25/912 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1327550085; called by muse, mutect2
- DCAF4L2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 36/793 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs755701425, COSV60476952, COSV60481637; called by muse, mutect2
- DPPA3 | c.327G>C p.T109= | Splice Region (SNP) | VAF 56/609 reads (9%) | catalogued as rs770300091; called by muse, mutect2
- GLYATL3 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 58/586 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225825213; called by muse, mutect2
- IFIH1 | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 73/687 reads (11%) | catalogued as rs761864966; called by muse, mutect2, varscan2
- LRTM2 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 46/472 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747004809, COSV54565773; called by muse, mutect2, varscan2
- MUC12 | c.10010G>A p.S3337N (on ENST00000379442; = p.S3194N on NM_001164462.1) | Missense Mutation (SNP) | VAF 122/4198 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV65183144; called by muse, mutect2
- PARD3B | c.2567G>A p.R856H (on ENST00000406610 / NM_001302769.2; = p.R787H on NM_057177.7) | Missense Mutation (SNP) | VAF 42/974 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as rs202062600, COSV100592522; called by muse, mutect2
- PLXNA2 | c.2606C>A p.P869Q | Missense Mutation (SNP) | VAF 102/848 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65437582; called by muse, mutect2, varscan2
- SYNJ2 | c.3403C>A p.Q1135K | Missense Mutation (SNP) | VAF 74/746 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.304); catalogued as COSV62898504; called by muse, mutect2
- UGT2B28 | c.1579A>G p.K527E | Missense Mutation (SNP) | VAF 210/899 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV100158967; called by muse, mutect2, varscan2
- WAPL | c.809A>G p.N270S | Missense Mutation (SNP) | VAF 67/603 reads (11%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs772249288; called by muse, mutect2, varscan2
- ANK3 | c.12955A>T p.K4319* (on ENST00000280772 / NM_001320874.2; = p.K943* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 57/677 reads (8%) | called by muse, mutect2
- ANKRD9 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 50/488 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATG4C | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 39/386 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- BEND2 | c.1249G>C p.D417H | Missense Mutation (SNP) | VAF 22/814 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- CACNA1E | c.5318C>T p.P1773L | Missense Mutation (SNP) | VAF 34/1130 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CBFB | c.173T>G p.V58G | Missense Mutation (SNP) | VAF 40/492 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- CEP170 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 32/686 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.035); called by muse, mutect2
- DCAF8L1 | c.1024A>C p.M342L | Missense Mutation (SNP) | VAF 222/867 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF18B | c.1895C>A p.P632Q (on ENST00000593135 / NM_001265577.2; = p.P644Q on NM_001264573.2) | Missense Mutation (SNP) | VAF 85/366 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- LCE1B | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 88/800 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDZD8 | c.416T>G p.L139R | Missense Mutation (SNP) | VAF 49/391 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PHLDB1 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 133/753 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLK5 | c.944G>T p.S315I | Missense Mutation (SNP) | VAF 160/452 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- POTEC | c.1354A>T p.S452C | Missense Mutation (SNP) | VAF 36/742 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- PREX1 | c.2879A>G p.H960R | Missense Mutation (SNP) | VAF 54/887 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); called by muse, mutect2
- RAB3GAP1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 90/1200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TMPRSS13 | c.1421T>C p.L474P | Missense Mutation (SNP) | VAF 75/1112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- UNC5D | c.718A>G p.R240G | Missense Mutation (SNP) | VAF 247/1306 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH23 | c.9069C>T p.D3023= | Silent (SNP) | VAF 60/606 reads (10%) | catalogued as COSV99818760; called by muse, mutect2
- EXOC7 | c.51G>A p.K17= | Silent (SNP) | VAF 220/810 reads (27%) | catalogued as rs747845989; called by muse, mutect2, varscan2
- HSFX3 | c.405G>A p.T135= | Silent (SNP) | VAF 94/1628 reads (6%) | called by muse, mutect2
- L1CAM | c.387G>T p.R129= | Silent (SNP) | VAF 110/1198 reads (9%) | catalogued as COSV62827072; called by muse, mutect2
- NEURL1B | c.525G>A p.P175= | Silent (SNP) | VAF 41/380 reads (11%) | called by muse, mutect2, varscan2
- RNF17 | c.6G>A p.A2= | Silent (SNP) | VAF 84/1142 reads (7%) | catalogued as rs775398893, COSV55045423; called by muse, mutect2
- SHC2 | c.855C>T p.G285= | Silent (SNP) | VAF 34/492 reads (7%) | catalogued as rs1485973047; called by muse, mutect2
- TKT | c.1251C>T p.C417= | Silent (SNP) | VAF 98/1276 reads (8%) | catalogued as rs367812486; called by muse, mutect2
- TMEM165 | c.936A>G p.A312= | Silent (SNP) | VAF 60/909 reads (7%) | called by muse, mutect2
- TRPM1 | c.1491G>A p.E497= | Silent (SNP) | VAF 178/742 reads (24%) | catalogued as rs758515250; called by muse, mutect2, varscan2
- UGT2B28 | c.561G>T p.L187= | Silent (SNP) | VAF 95/1358 reads (7%) | catalogued as rs1175823842; called by muse, mutect2
- BTBD11 | c.1135+530G>A | Intron (SNP) | VAF 44/542 reads (8%) | called by muse, mutect2
- C1QL2 | c.-85C>T | 5'UTR (SNP) | VAF 63/258 reads (24%) | called by muse, mutect2, varscan2
- CCT6A | c.1348-58T>C | Intron (SNP) | VAF 10/145 reads (7%) | called by muse, mutect2
- GPC1 | c.*36G>A | 3'UTR (SNP) | VAF 58/800 reads (7%) | called by muse, mutect2
- GRIA1 | c.82+1221G>A | Intron (SNP) | VAF 14/184 reads (8%) | catalogued as rs997037310; called by muse, mutect2
- LGALS9C | c.761+23C>T | Intron (SNP) | VAF 138/951 reads (15%) | called by muse, mutect2, varscan2
- SPHK1 | c.-24C>A | 5'UTR (SNP) | VAF 87/792 reads (11%) | catalogued as COSV60064439; called by muse, mutect2, varscan2
- TTC6 | c.-42G>C | 5'UTR (SNP) | VAF 22/466 reads (5%) | called by muse, mutect2
- UMPS | c.1273+19C>T | Intron (SNP) | VAF 57/531 reads (11%) | catalogued as rs1380965001; called by muse, mutect2, varscan2
- ZNF446 | c.803-18G>T | Intron (SNP) | VAF 58/910 reads (6%) | catalogued as COSV59991524; called by muse, mutect2
